HCMI case HCM-EXPT-1042-C50 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Complex Epithelial Neoplasms; Primary site: Breast.
https://portal.gdc.cancer.gov/cases/a699ebed-f444-43cc-861f-3595ac15dda5

Demographics
Sex at birth: female; Year of birth: 1953.

Diagnoses (1)
1. Metaplastic carcinoma, NOS: ICD-O-3 morphology code: 8575/3; ICD-10 code: C50.9; Tissue or organ of origin: Breast, NOS; Site of resection or biopsy: Breast, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 64.6 years (23,612 days); Prior treatment: No.
   Recorded as not given: neoadjuvant treatment (type not reported).

Biospecimens (1 sample; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample HCM-EXPT-1042-C50-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
  Slide HCM-EXPT-1042-C50-01A-01-S1-HE: Section location: Top; Percent tumor cells: 3; Percent tumor nuclei: 15; Percent normal cells: 8; Percent necrosis: 0; Percent stromal cells: 89; Percent lymphocyte infiltration: 20; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 0.
  Slide HCM-EXPT-1042-C50-01A-01-S2-HE: Section location: Bottom; Percent tumor cells: 6; Percent tumor nuclei: 50; Percent normal cells: 6; Percent necrosis: 0; Percent stromal cells: 88; Percent lymphocyte infiltration: 18; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
